Somatic mutation profile of tumor specimen 0DWVFJ from CCDI case PBCPFJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myxofibrosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 10.1 years (3,672 days).
Specimen 0DWVFJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04caff5c-3107-4e50-9490-57fd860daebc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a6207c6-6f82-46d0-8d8d-edc4810e31af

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHGA9 | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 53/629 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKHD1L1 | c.1361A>C p.Q454P | Missense Mutation (SNP) | VAF 282/607 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PRKAG1 | c.300A>G p.K100= | Silent (SNP) | VAF 123/334 reads (37%) | catalogued as rs771822493; called by muse, mutect2, varscan2
- AP1S1 | c.3+42G>T | Intron (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2
